Surgical pathology report (de-identified scan), TCGA case TCGA-05-4390, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4390-01A (Primary Tumor).

Main diagnosis/diagnoses: Peripheral bronchopulmonary, histologically mixed adenocarcinoma of the right upper lobe of the lung with predominant acinar and a smaller large-cell solid component and localization in S2.

TNM classification: pT2, pN0, R0, stage IB..

C 34.1; M 8255/3.

Comment/supplementary remark: the tumor lies at the junction with S1 and has infiltrated the retracted visceral pleura that is enlarged with fibrosis. The resection margin of the bronchus and vessels and all the lymph nodes removed (samples 1.) to 7.) are tumor-free.

Source: NCI Genomic Data Commons file 3b456ba0-573a-416a-ad19-95f431843246 (TCGA-05-4390.2E3FAAD1-3A5E-4EFB-96EA-8C44839FEC6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).